Somatic mutation profile of tumor specimen MP2PRT-PAUKVW-TMP1-A (aliquot MP2PRT-PAUKVW-TMP1-A-1-0-D-A818-36) from MP2PRT case MP2PRT-PAUKVW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.2 years (800 days).
Specimen MP2PRT-PAUKVW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3ef91494-b27b-45be-920e-5abf9048617d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUKVW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUKVW-NB1-A-1-0-D-A818-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/10d7945b-c6fc-4c35-ade2-b264fb746e14

The open-access MAF lists 6 somatic variants for this specimen: 2 protein-altering or splice-affecting, 4 silent.
By variant classification: Silent 4, Missense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.38G>A p.G13D | Missense Mutation (SNP) | VAF 49/264 reads (19%) | hotspot (GDC flag); SIFT deleterious (0.05); PolyPhen benign (0.323); catalogued as rs121434596, CM071907, COSV54736416, COSV54736480, COSV54736793; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SYNE1 | c.15572G>A p.R5191H (on ENST00000367255 / NM_182961.4; = p.R5120H on NM_033071.3) | Missense Mutation (SNP) | VAF 82/352 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1417065548, COSV99555377; called by muse, mutect2
- CABS1 | c.567C>T p.S189= | Silent (SNP) | VAF 82/233 reads (35%) | catalogued as COSV99909197; called by muse, mutect2, varscan2
- PSAPL1 | c.429G>A p.L143= | Silent (SNP) | VAF 30/528 reads (6%) | catalogued as rs1488182247; called by muse, mutect2
- SNTG2 | c.861G>A p.A287= | Silent (SNP) | VAF 111/424 reads (26%) | catalogued as rs781407119, COSV57974708; called by muse, mutect2, varscan2
- TDRD12 | c.2235C>T p.T745= | Silent (SNP) | VAF 84/298 reads (28%) | catalogued as rs754001972; called by muse, mutect2, varscan2
